Somatic mutation profile of tumor specimen TCGA-D7-A4YY-01A (aliquot TCGA-D7-A4YY-01A-11D-A25D-08) from TCGA case TCGA-D7-A4YY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.0 years (22,287 days).
Specimen TCGA-D7-A4YY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8dbba43-0ab4-4ec4-ab34-99a57f260250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4YY-10A (Blood Derived Normal), aliquot TCGA-D7-A4YY-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5653eb92-abce-4d4c-a08f-d13b0cb1dca4

The open-access MAF lists 559 somatic variants for this specimen: 388 protein-altering or splice-affecting, 156 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 156, Frame Shift Del 68, Frame Shift Ins 31, Nonsense Mutation 12, In Frame Del 7, Intron 6, Splice Site 5, RNA 5, Splice Region 4, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CENPF | c.5920dup p.T1974Nfs*9 | Frame Shift Ins (INS) | VAF 34/80 reads (43%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- HLCS | c.977dup p.E327Rfs*25 | Frame Shift Ins (INS) | VAF 105/447 reads (23%) | catalogued as rs1555955827; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PKD2 | c.2159dup p.N720Kfs*5 | Frame Shift Ins (INS) | VAF 26/134 reads (19%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- PNLIPRP3 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.225); catalogued as COSV65046911, COSV65048763; called by muse, mutect2, varscan2
- ABCB4 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs753551693, COSV55937412; called by muse, mutect2, varscan2
- ABCC4 | c.3210+1G>A p.X1070_splice | Splice Site (SNP) | VAF 21/110 reads (19%) | catalogued as COSV65314500; called by muse, mutect2, varscan2
- ABCC8 | c.4228G>A p.A1410T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as rs975338030, COSV56852933; called by muse, mutect2, varscan2
- ABCG1 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs748557431, COSV59206683; called by muse, mutect2, varscan2
- ADAMTS2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs752634323, COSV51072804, COSV51081870; called by muse, mutect2, varscan2
- ADCK1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs757237522, COSV53082582; called by muse, mutect2, varscan2
- ADGRB1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs76763828, COSV60091570; called by muse, mutect2, varscan2
- ADGRV1 | c.3490C>T p.Q1164* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as COSV67988823; called by muse, mutect2, varscan2
- ADNP | c.2345C>T p.T782I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV62425982; called by muse, mutect2, varscan2
- ADNP2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs746461633, COSV51540226; called by muse, mutect2, varscan2
- AGER | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV61248054; called by muse, mutect2, varscan2
- AL121899.2 | c.906G>A p.A302= | Splice Region (SNP) | VAF 87/201 reads (43%) | catalogued as rs201000537; called by muse, mutect2, varscan2
- ALDOB | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV66398127; called by muse, mutect2, varscan2
- ALG10 | c.981dup p.V328Cfs*18 | Frame Shift Ins (INS) | VAF 33/105 reads (31%) | catalogued as rs768493124; called by mutect2, pindel, varscan2
- ALMS1 | c.4115G>A p.G1372D | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as rs1439442789, COSV52513563; called by muse, mutect2, varscan2
- ALPL | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs745704006, COSV66376382; called by muse, mutect2, varscan2
- ANK3 | c.2419G>A p.G807S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757859236, COSV55065590; called by muse, mutect2, varscan2
- ANKS6 | c.1636C>A p.L546I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV62050907; called by muse, mutect2, varscan2
- AP3B2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1393295194, COSV55611161; called by muse, mutect2, varscan2
- APBA2 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755413618, COSV68792602; called by muse, mutect2, varscan2
- APBB2 | c.1000T>C p.S334P (on ENST00000295974 / NM_001166050.2; = p.S335P on NM_004307.2) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV55955872; called by muse, mutect2, varscan2
- ARAP1 | c.2309G>T p.S770I (on ENST00000393609 / NM_001040118.2; = p.S525I on NM_015242.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV61992149; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs374330946, COSV59477380; called by muse, mutect2, varscan2
- ATP7B | c.1820A>C p.K607T | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as COSV54440258; called by muse, mutect2, varscan2
- B3GAT2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57771024, COSV57773075; called by muse, mutect2
- BAG6 | c.2965del p.Q989Sfs*85 (on ENST00000676571; = p.Q942Sfs*85 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 41/91 reads (45%) | catalogued as rs778695310; called by mutect2, pindel, varscan2
- BARX1 | c.225C>T p.A75= | Splice Region (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54159317; called by muse, mutect2
- BCL9L | c.3512del p.P1171Rfs*32 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as COSV99419124; called by mutect2, pindel, varscan2
- BRINP3 | c.1527A>C p.E509D | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV66529497; called by muse, mutect2, varscan2
- BTN3A1 | c.877A>C p.M293L | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV50025018; called by muse, mutect2, varscan2
- C10orf71 | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV60509499; called by muse, mutect2, varscan2
- CACNA1H | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV61995144; called by muse, mutect2
- CAMK2G | c.1519G>A p.A507T (on ENST00000423381 / NM_001367518.1; = p.A444T on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55215876; called by muse, mutect2, varscan2
- CAPN5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142613341; called by muse, varscan2
- CAPN6 | c.1307T>G p.L436R | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60695688; called by muse, mutect2, varscan2
- CASZ1 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1018449961, COSV100680668, COSV59737967; called by muse, mutect2, varscan2
- CBFA2T3 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV51929200; called by muse, mutect2, varscan2
- CCDC136 | c.1454A>T p.K485M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52801431; called by muse, mutect2, varscan2
- CCDC158 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs765370797, COSV66356498; called by muse, mutect2, varscan2
- CCDC97 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.258); catalogued as COSV54190844; called by muse, mutect2, varscan2
- CDH12 | c.1541A>G p.D514G | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66418520; called by muse, mutect2, varscan2
- CDH22 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64838307; called by muse, mutect2, varscan2
- CDKN2AIP | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774290649, COSV56627492; called by muse, mutect2, varscan2
- CENPB | c.782A>G p.Y261C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60147953; called by muse, mutect2, varscan2
- CFHR3 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.173); catalogued as COSV66402600; called by muse, mutect2, varscan2
- CHRDL1 | c.22T>G p.F8V (on ENST00000372045; = p.F14V on NM_145234.4) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54326401; called by muse, mutect2, varscan2
- CHRNB2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63808604; called by muse, mutect2, varscan2
- CHST13 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs1308140476, COSV60042600; called by muse, mutect2, varscan2
- CLDN9 | c.560dup p.P188Afs*96 | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | catalogued as rs753671764; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | catalogued as rs369752219; called by mutect2, varscan2
- CNTNAP5 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV101443000, COSV70478849; called by muse, mutect2, varscan2
- COL11A1 | c.3607C>T p.P1203S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62187997, COSV62188652; called by muse, mutect2, varscan2
- COL22A1 | c.4075C>A p.P1359T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57344495; called by muse, mutect2, varscan2
- COL26A1 | c.553A>G p.I185V (on ENST00000313669 / NM_001278563.3; = p.I183V on NM_133457.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.502); catalogued as COSV58127219; called by muse, mutect2, varscan2
- COL8A1 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766014652, COSV53737039; called by muse, mutect2, varscan2
- COPG1 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59115029; called by muse, mutect2, varscan2
- CPS1 | c.3569A>G p.H1190R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as rs755294410, COSV51814778; called by muse, varscan2
- CR1 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV65459651; called by muse, mutect2, varscan2
- CRACDL | c.426del p.L143Ffs*11 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as COSV67409844; called by mutect2, pindel, varscan2
- CRACR2A | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs768277859, COSV52910900; called by muse, mutect2
- CSTF2T | c.1352G>T p.R451M | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58656860; called by muse, mutect2, varscan2
- CWF19L2 | c.2261dup p.L754Ffs*4 | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | catalogued as rs1376220048; called by mutect2, varscan2
- DARS2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1064797125, COSV53406433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF6 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV56578978; called by muse, mutect2
- DCDC2 | c.1161A>C p.Q387H | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as COSV65828602; called by muse, mutect2, varscan2
- DCUN1D4 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.326); catalogued as COSV58123610; called by muse, mutect2, varscan2
- DDIAS | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV61272536; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND4C | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1394447429, COSV66822528; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs373108427; called by mutect2, varscan2
- DMAP1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.129); catalogued as COSV60001099; called by muse, mutect2, varscan2
- DNAJA3 | c.633C>T p.Y211= | Splice Region (SNP) | VAF 54/149 reads (36%) | catalogued as rs755520110, COSV52162630; called by muse, mutect2, varscan2
- DNM3 | c.1768C>T p.H590Y (on ENST00000355305 / NM_001350206.2; = p.H580Y on NM_015569.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1184961269, COSV62461393; called by muse, mutect2
- DOCK9 | c.1249G>A p.V417I (on ENST00000376460 / NM_001366676.2; = p.V418I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs750433698, COSV59634129; called by muse, mutect2, varscan2
- DPYSL3 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs758085369, COSV58328118; called by muse, mutect2, varscan2
- DSCAM | c.2225G>T p.R742L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68027081, COSV68029910; called by muse, mutect2, varscan2
- DUS3L | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV57832381; called by muse, mutect2, varscan2
- EIF2AK4 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs765950157, COSV55470081; called by muse, mutect2, varscan2
- EMX2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as rs376235349; called by muse, mutect2, varscan2
- EPB41L3 | c.1597A>G p.K533E | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as COSV59458794, COSV59462373; called by muse, mutect2, varscan2
- EPHA8 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.659); catalogued as rs182997024, COSV51274410, COSV99385913; called by muse, mutect2, varscan2
- EPHB1 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67664504; called by muse, mutect2, varscan2
- ERICH3 | c.4073A>G p.E1358G | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs756670925, COSV58610786; called by muse, mutect2, varscan2
- ESS2 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 167/441 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs533003983, COSV52817462; called by muse, mutect2, varscan2
- ESX1 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV65424653; called by muse, mutect2
- EXOSC10 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs764219569, COSV58664676; called by muse, mutect2, varscan2
- F12 | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV53691895; called by muse, mutect2, varscan2
- FAM221A | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV61388090; called by muse, mutect2, varscan2
- FAM76B | c.153C>T p.S51= | Splice Region (SNP) | VAF 7/15 reads (47%) | catalogued as COSV57689216; called by muse, mutect2, varscan2
- FAM83H | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1554623098, COSV66354083; called by muse, mutect2, varscan2
- FAT4 | c.3690A>C p.L1230F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV67890955; called by muse, mutect2, varscan2
- FAT4 | c.10860G>T p.E3620D | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58678167; called by muse, mutect2, varscan2
- FBN2 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs150506063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL15 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV50048291; called by muse, mutect2, varscan2
- FCRL1 | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63826081, COSV63826278; called by muse, mutect2, varscan2
- FKBP10 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201944190; called by muse, mutect2, varscan2
- FOCAD | c.2321T>C p.L774S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58102425; called by muse, mutect2, varscan2
- FOXL2 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV57728109; called by muse, mutect2, varscan2
- FOXO4 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV58575357; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 54/149 reads (36%) | catalogued as rs752538869; called by mutect2, varscan2
- FYN | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1465963577, COSV57609576; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GADD45B | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1478757278, COSV53126307; called by muse, mutect2, varscan2
- GAL3ST3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.944); catalogued as rs1290136225, COSV61749009; called by muse, mutect2, varscan2
- GALNT17 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61169837; called by muse, mutect2, varscan2
- GANAB | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1465649718, COSV60466138; called by muse, mutect2, varscan2
- GBA2 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.045); catalogued as COSV65239823; called by muse, mutect2, varscan2
- GCM1 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV52522565; called by muse, mutect2, varscan2
- GCN1 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56110141; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs768450027; called by mutect2, varscan2
- GHITM | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV64538783; called by muse, mutect2, varscan2
- GLRA3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864654; called by muse, mutect2, varscan2
- GPC2 | c.1666del p.A556Hfs*31 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs753572388; called by mutect2, pindel, varscan2
- GPLD1 | c.2302C>G p.L768V | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57758739; called by muse, mutect2, varscan2
- GRIK4 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270557423, COSV70803918; called by muse, mutect2, varscan2
- GTDC1 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV53998642; called by muse, mutect2, varscan2
- GTF3C4 | c.721A>T p.R241W | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64645596; called by muse, mutect2, varscan2
- HBS1L | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV63201727; called by muse, mutect2, varscan2
- HIC2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68042462; called by muse, mutect2, varscan2
- HIP1 | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV61187966; called by muse, mutect2, varscan2
- HMCN1 | c.14551C>A p.R4851S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV54889970, COSV54913426; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPU | c.2228A>G p.Y743C (on ENST00000283179; = p.Y805C on NM_004501.3) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51692177; called by muse, mutect2, varscan2
- HOXA11 | c.895del p.I299Lfs*30 | Frame Shift Del (DEL) | VAF 21/115 reads (18%) | catalogued as rs777829525; called by mutect2, varscan2
- HPSE2 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV65193047; called by muse, mutect2, varscan2
- HSP90AA1 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as COSV53489578; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR3E | c.1293G>T p.M431I (on ENST00000415389 / NM_001256613.1; = p.M446I on NM_182589.2) | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV58947530; called by muse, mutect2
- IGFBP5 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV52082083, COSV99288876; called by muse, mutect2, varscan2
- IGKV3D-20 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs1200529376; called by muse, mutect2, varscan2
- INPP1 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59416450; called by muse, mutect2, varscan2
- IQSEC1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1322692577, COSV56225345; called by muse, mutect2, varscan2
- IRS1 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59337604; called by muse, mutect2, varscan2
- ITPR3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 173/258 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV65406694, COSV65410545; called by muse, mutect2, varscan2
- JAZF1 | c.333del p.V112* | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as COSV52236122; called by mutect2, pindel, varscan2
- KAT6A | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378339251, COSV55907973; called by muse, mutect2, varscan2
- KCNA5 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV52905593; called by muse, mutect2, varscan2
- KCNC4 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV63925997; called by muse, mutect2, varscan2
- KCNK16 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 56/121 reads (46%) | catalogued as COSV64678528; called by muse, mutect2, varscan2
- KCNK9 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57284083; called by muse, mutect2, varscan2
- KCNN1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs749207776, COSV55836817; called by muse, mutect2, varscan2
- KCNQ5 | c.2439A>C p.E813D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV59667837; called by muse, mutect2, varscan2
- KDM3B | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1287614598, COSV58692322; called by muse, mutect2, varscan2
- KDM5A | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101239025, COSV66993833; called by muse, mutect2, varscan2
- KIAA1217 | c.4710G>T p.K1570N | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56818892; called by muse, mutect2, varscan2
- KIF1A | c.4735C>T p.R1579* (on ENST00000320389 / NM_001379639.1; = p.R1571* on NM_004321.8 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV57493483; called by muse, mutect2, varscan2
- KIF26A | c.1665C>A p.D555E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59467951; called by muse, mutect2, varscan2
- KMT2A | c.11524G>A p.G3842S | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63288142; called by muse, mutect2, varscan2
- KRTAP10-5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs371928961; called by muse, mutect2, varscan2
- KRTAP13-2 | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV67762109; called by muse, mutect2, varscan2
- KRTAP6-3 | c.22A>T p.M8L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | PolyPhen possibly damaging (0.625); catalogued as COSV66963086; called by muse, mutect2, varscan2
- KTN1 | c.3961_3963del p.K1321del (on ENST00000395314 / NM_001271014.2; = p.K1264del on NM_004986.4) | In Frame Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs1304070713; called by mutect2, pindel, varscan2
- L3MBTL2 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as COSV53434127; called by muse, mutect2, varscan2
- LAMA1 | c.1351T>G p.C451G | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67539466; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LIG1 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1218996619, COSV54393312; called by muse, mutect2, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | catalogued as rs745989900; called by mutect2, varscan2
- LILRA2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs375220153, COSV52189786; called by muse, mutect2, varscan2
- LPA | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); catalogued as rs1316313933, COSV60304527; called by muse, mutect2
- LRP1B | c.2585G>A p.W862* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV63341825, COSV63341845; called by muse, mutect2, varscan2
- LRRC37B | c.2492C>A p.S831* | Nonsense Mutation (SNP) | VAF 44/74 reads (59%) | catalogued as COSV58953090; called by muse, mutect2, varscan2
- LRRC7 | c.169G>T p.G57C (on ENST00000651989 / NM_001370785.2; = p.G24C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50496505; called by muse, mutect2, varscan2
- LRRC7 | c.717A>C p.E239D (on ENST00000651989 / NM_001370785.2; = p.E206D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV50409414; called by muse, mutect2, varscan2
- LYAR | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 8/225 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs1244909884, COSV100603450; called by muse, mutect2
- MAB21L1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as COSV59785079; called by muse, mutect2, varscan2
- MAN2B1 | c.1690C>A p.L564M | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55473029; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1477479894, COSV51722277; called by muse, mutect2, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs767720617; called by mutect2, varscan2
- MCM3 | c.312G>C p.Q104H (on ENST00000229854 / NM_001366374.2; = p.Q94H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV57718272; called by muse, mutect2, varscan2
- MEF2D | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV61729329; called by muse, mutect2, varscan2
- METTL22 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as rs1250424946, COSV50837998; called by muse, mutect2, varscan2
- METTL7B | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as COSV57697108; called by muse, mutect2, varscan2
- MGA | c.877C>A p.R293S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV54957207, COSV99580096; called by muse, mutect2, varscan2
- MGAT4A | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs141026005; called by muse, mutect2, varscan2
- MMP3 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55406792; called by muse, mutect2, varscan2
- MN1 | c.3091G>A p.G1031R | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs758293540, COSV56559601; called by muse, mutect2, varscan2
- MRC1 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs970799233; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 39/147 reads (27%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MYO1D | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs765168629, COSV59016776; called by muse, mutect2, varscan2
- MYO5B | c.2213A>G p.K738R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs779113043, COSV53222767; called by muse, mutect2, varscan2
- NAGLU | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs775364669, COSV56795356; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs763376147; called by mutect2, varscan2
- NFATC2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs199662497; called by muse, mutect2, varscan2
- NHLRC1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV61481646; called by muse, mutect2, varscan2
- NIPAL3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs200419498, COSV50231104; called by muse, mutect2, varscan2
- NKX6-1 | c.237del p.L80Sfs*23 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs745904099; called by mutect2, varscan2
- NLRC5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs201268786, COSV52657964; called by muse, mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 41/98 reads (42%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NLRP7 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749577734, COSV100051551; called by muse, varscan2
- NOL3 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV50457960; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NR1I2 | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV61977850; called by muse, mutect2, varscan2
- NR5A2 | c.1626A>C p.*542Yext*43 (on ENST00000367362 / NM_205860.3; = p.*496Yext*43 on NM_003822.5) | Nonstop Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV52645510; called by muse, mutect2, varscan2
- NUDT10 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1485048141, COSV62854257; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 43/114 reads (38%) | catalogued as rs762804106; called by mutect2, varscan2
- NXPE4 | c.1236G>T p.E412D (on ENST00000375478 / NM_001077639.2; = p.E128D on NM_017678.3) | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV64943988; called by muse, mutect2, varscan2
- OLFM1 | c.878G>A p.R293H (on ENST00000371793 / NM_001282611.2; = p.R275H on NM_014279.5) | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); catalogued as rs1259537651, COSV53279856; called by muse, mutect2, varscan2
- OR10X1 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV63767561; called by muse, mutect2, varscan2
- OR11L1 | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63314872; called by muse, mutect2, varscan2
- OR4F6 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs1456726640, COSV61027103; called by muse, mutect2, varscan2
- OR6C75 | c.763T>G p.F255V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV58552847; called by muse, mutect2, varscan2
- OR6N1 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.996); catalogued as COSV58649178; called by muse, mutect2, varscan2
- ORM1 | c.436+2T>C p.X146_splice | Splice Site (SNP) | VAF 21/88 reads (24%) | catalogued as COSV52278998, COSV52279893; called by muse, mutect2, varscan2
- OSBPL8 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as COSV53885145; called by muse, mutect2, varscan2
- OVGP1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs752564902, COSV63858895; called by muse, mutect2, varscan2
- PABPC5 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV57041632; called by muse, mutect2, varscan2
- PAK2 | c.1350G>T p.R450S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100505816; called by muse, mutect2, varscan2
- PAK4 | c.1542dup p.Y515Lfs*124 | Frame Shift Ins (INS) | VAF 37/83 reads (45%) | catalogued as rs769136911; called by mutect2, pindel, varscan2
- PARN | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs750721134, COSV100420612; called by muse, mutect2, varscan2
- PCDH8 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 70/205 reads (34%) | catalogued as COSV58813568; called by muse, mutect2, varscan2
- PCK2 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.477); catalogued as rs61737097, COSV53749514, COSV99394484; called by muse, mutect2, varscan2
- PCNT | c.9211A>G p.R3071G | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs886057194, COSV64030001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCP4L1 | c.69del p.A24Lfs*17 | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | catalogued as COSV101552221; called by mutect2, pindel, varscan2
- PDIA5 | c.1157dup p.P387Afs*44 | Frame Shift Ins (INS) | VAF 46/140 reads (33%) | catalogued as rs766425459; called by mutect2, varscan2
- PDS5B | c.1751C>G p.T584S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV59729607; called by mutect2, varscan2
- PEG3 | c.2972A>G p.H991R | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV55638170; called by muse, mutect2, varscan2
- PELI2 | c.593del p.G198Afs*73 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | catalogued as COSV50713636; called by mutect2, pindel, varscan2
- PHLDB2 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV67313037; called by muse, mutect2, varscan2
- PKD1 | c.7637A>G p.H2546R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs772999733, COSV51919478; called by muse, mutect2, varscan2
- PKLR | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs1270838814, COSV61361703; called by muse, mutect2, varscan2
- PLEC | c.4373C>T p.T1458M (on ENST00000322810 / NM_201380.4; = p.T1348M on NM_000445.5) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs782146862, COSV59654257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R16A | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV52953693; called by muse, mutect2, varscan2
- PPP1R3A | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52885824; called by muse, mutect2
- PRKD3 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV50018015; called by muse, mutect2, varscan2
- PTK2B | c.2476_2478del p.E826del | In Frame Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs764367017; called by pindel, varscan2
- PTPN12 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200867808, COSV50363113; called by muse, mutect2
- PTPRZ1 | c.3641T>G p.V1214G | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV66440319; called by muse, mutect2, varscan2
- PXDN | c.3137C>T p.T1046M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375863606; called by muse, mutect2, varscan2
- RAB39A | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572739559, COSV57695047; called by muse, mutect2, varscan2
- RABAC1 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as COSV55771073; called by muse, mutect2, varscan2
- RAD54L2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs952375132, COSV56579615; called by muse, mutect2, varscan2
- RANBP2 | c.7916C>T p.T2639I | Missense Mutation (SNP) | VAF 99/301 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as rs955573902, COSV51703319; called by muse, mutect2, varscan2
- RANBP9 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs112516735, COSV50582563; called by muse, mutect2, varscan2
- RANBP9 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 49/73 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV50582599, COSV99163521; called by muse, mutect2, varscan2
- REC8 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV61017006; called by muse, mutect2, varscan2
- RGS20 | c.451del p.H151Ifs*3 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs35570213; called by mutect2, varscan2
- RNF186 | c.545T>A p.L182H | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64296827; called by muse, mutect2, varscan2
- ROCK1 | c.1644A>T p.E548D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV67696876; called by muse, mutect2, varscan2
- RPH3AL | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs371456304, COSV58744026; called by muse, mutect2
- RTBDN | c.491G>A p.R164H (on ENST00000393233 / NM_001270444.1; = p.R196H on NM_031429.2) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as rs781570616, COSV59806642; called by muse, mutect2, varscan2
- RTN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV50730916; called by muse, mutect2
- RXFP3 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57506573; called by muse, mutect2, varscan2
- RYR2 | c.12292G>A p.V4098I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as rs1047248475, COSV63661279, COSV63692480; called by muse, mutect2, varscan2
- SDHD | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs878854595, COSV65019567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINH1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs535510332, COSV63998178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFMBT2 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62811981; called by muse, mutect2, varscan2
- SIK3 | c.3955G>T p.G1319C (on ENST00000445177 / NM_001366686.2; = p.G1277C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV52617705, COSV52625253; called by muse, mutect2, varscan2
- SLC11A1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV51915970, COSV51917866; called by muse, mutect2, varscan2
- SLC19A3 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV51451677; called by muse, mutect2, varscan2
- SLC49A4 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV53747848; called by muse, mutect2, varscan2
- SLC5A4 | c.896A>G p.Q299R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756791616, COSV56671565, COSV99831680; called by muse, mutect2, varscan2
- SLC9A1 | c.1285G>C p.V429L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56054527; called by muse, mutect2, varscan2
- SLFN5 | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55481935; called by muse, mutect2, varscan2
- SMARCA2 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV61809361; called by muse, mutect2, varscan2
- SMCR8 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1300289529, COSV58178749; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs768873484; called by mutect2, varscan2
- SOGA3 | c.1859A>T p.D620V | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV64107277; called by muse, mutect2, varscan2
- SORBS2 | c.65G>A p.S22N (on ENST00000284776 / NM_021069.5; = p.S68N on NM_003603.6) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); catalogued as COSV53005315; called by muse, mutect2, varscan2
- SORCS1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as rs1480316116, COSV53878887, COSV99547749; called by muse, mutect2, varscan2
- SOX5 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58628809, COSV58652994; called by muse, mutect2, varscan2
- SPATA20 | c.1304T>A p.L435H (on ENST00000356488 / NM_001258372.1; = p.L451H on NM_022827.4) | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV50067620; called by muse, mutect2, varscan2
- SPATA32 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749017532, COSV59304132; called by muse, mutect2, varscan2
- SPATC1 | c.1742C>G p.A581G | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV66299252; called by muse, mutect2, varscan2
- SPECC1L | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as COSV58659523; called by muse, mutect2, varscan2
- SPEN | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65363242, COSV65363381; called by muse, mutect2, varscan2
- SPEN | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV65363887; called by muse, mutect2, varscan2
- SPTA1 | c.5097A>C p.Q1699H | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV63752409, COSV63755786; called by muse, mutect2, varscan2
- SSU72P8 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs201786412; called by muse, mutect2, varscan2
- SSX2IP | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs936520365, COSV60551433; called by muse, mutect2, varscan2
- ST3GAL5 | c.622G>A p.A208T (on ENST00000377332; = p.A248T on NM_003896.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1409195681, COSV60386255; called by muse, mutect2, varscan2
- ST6GAL2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | PolyPhen benign (0); catalogued as rs781338462, COSV64525788; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | PolyPhen benign (0.276); catalogued as COSV60338565; called by muse, mutect2, varscan2
- STARD3 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV59223972; called by muse, mutect2, varscan2
- STAT5A | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100604335; called by muse, mutect2, varscan2
- STX11 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62449644; called by muse, mutect2, varscan2
- SYNE1 | c.10474C>T p.R3492C (on ENST00000367255 / NM_182961.4; = p.R3499C on NM_033071.3) | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs531503159, COSV55022643; called by muse, mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | catalogued as rs746556335; called by mutect2, varscan2
- TBC1D2 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs765967977, COSV59786103; called by muse, mutect2, varscan2
- TENM2 | c.2593C>A p.P865T (on ENST00000518659 / NM_001122679.2; = p.P633T on NM_001080428.3) | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69134386; called by muse, mutect2, varscan2
- THBS2 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64679968; called by muse, mutect2, varscan2
- TIGAR | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224121261, COSV51628591; called by muse, mutect2, varscan2
- TMEM236 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1554836402; called by muse, mutect2, varscan2
- TMEM266 | c.769-2A>C p.X257_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV66380051; called by muse, mutect2, varscan2
- TNRC18 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs748598951, COSV68087666; called by muse, mutect2, varscan2
- TOMM20 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 108/332 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV64012980; called by muse, mutect2, varscan2
- TRANK1 | c.4822C>T p.R1608W | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370789776; called by muse, mutect2, varscan2
- TRERF1 | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs372620033; called by muse, mutect2, varscan2
- TRPM4 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53261570, COSV53269665; called by muse, mutect2, varscan2
- TRRAP | c.11339C>T p.A3780V (on ENST00000359863 / NM_001244580.1; = p.A3751V on NM_003496.3) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as rs560766520, COSV62816278; called by muse, mutect2, varscan2
- TSGA10IP | c.585del p.S196Vfs*34 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs767478344; called by mutect2, pindel, varscan2
- TTC12 | c.1446+1G>A p.X482_splice | Splice Site (SNP) | VAF 37/112 reads (33%) | catalogued as rs1555150641, COSV59098546; called by muse, mutect2, varscan2
- TTC25 | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV66368544; called by muse, mutect2, varscan2
- TXLNB | c.1634del p.P545Lfs*2 | Frame Shift Del (DEL) | VAF 52/177 reads (29%) | catalogued as rs751685574; called by mutect2, pindel, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- UNC13C | c.2369A>C p.K790T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as rs761297606, COSV52891743; called by muse, mutect2, varscan2
- USH1G | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); catalogued as COSV58882459; called by muse, mutect2, varscan2
- USP1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs1178522954, COSV60574829; called by muse, mutect2, varscan2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 60/156 reads (38%) | catalogued as rs751290466; called by mutect2, varscan2
- VCX | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV100406348, COSV58231864; called by muse, mutect2
- VIT | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.058); catalogued as COSV64897497; called by muse, mutect2
- VSX2 | c.249del p.L84Sfs*57 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs1033708386; called by mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 33/120 reads (28%) | catalogued as rs756173793; called by mutect2, varscan2
- YEATS4 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV56089166; called by muse, mutect2, varscan2
- ZER1 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV52566721; called by muse, mutect2, varscan2
- ZFHX4 | c.1356C>A p.N452K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.025); catalogued as COSV51456170; called by muse, mutect2, varscan2
- ZFHX4 | c.9480G>T p.Q3160H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV50618674, COSV51456279; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF133 | c.1024G>A p.V342M (on ENST00000316358 / NM_001352454.2; = p.V341M on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs369473920; called by muse, mutect2, varscan2
- ZNF257 | c.217A>G p.K73E | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1401823723, COSV71309748; called by muse, mutect2, varscan2
- ZNF395 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60429335; called by muse, mutect2, varscan2
- ZNF454 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 46/131 reads (35%) | catalogued as COSV60769104; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF587 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100299276; called by muse, mutect2, varscan2
- ZNF596 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs145428583; called by muse, mutect2, varscan2
- ZNF681 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV68074662; called by muse, mutect2, varscan2
- ZNF784 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as rs568241570, COSV57596318; called by muse, mutect2, varscan2
- ZNF878 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72156042; called by muse, varscan2
- ANKS6 | c.1175del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, varscan2
- AOC3 | c.490dup p.L164Pfs*92 | Frame Shift Ins (INS) | VAF 35/111 reads (32%) | called by mutect2, varscan2
- CCDC30 | c.1498del p.R500Efs*35 (on ENST00000340612; = p.R457Efs*35 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- COL16A1 | c.1373dup p.G459Wfs*47 | Frame Shift Ins (INS) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- COL7A1 | c.5324del p.P1775Lfs*66 | Frame Shift Del (DEL) | VAF 33/80 reads (41%) | called by mutect2, pindel, varscan2
- CSGALNACT2 | c.109del p.Q37Rfs*39 | Frame Shift Del (DEL) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- CYP4F3 | c.752dup p.D252* | Frame Shift Ins (INS) | VAF 82/271 reads (30%) | called by mutect2, varscan2
- DOCK6 | c.921del p.L308Cfs*22 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/114 reads (35%) | called by mutect2, pindel, varscan2
- ELF3 | c.33del p.F11Lfs*32 | Frame Shift Del (DEL) | VAF 60/189 reads (32%) | called by mutect2, pindel, varscan2
- ELOVL2 | c.415del p.T139Rfs*23 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | called by mutect2, pindel, varscan2
- FPR1 | c.173_174dup p.V59Qfs*8 | Frame Shift Ins (INS) | VAF 34/114 reads (30%) | called by mutect2, varscan2
- GALNT14 | c.742+1dup p.X248_splice | Splice Site (INS) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- GNPTAB | c.524del p.N175Tfs*38 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- GPR141 | c.690del p.F230Lfs*2 | Frame Shift Del (DEL) | VAF 61/187 reads (33%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- HLA-DRA | c.391_393del p.I131del | In Frame Del (DEL) | VAF 29/58 reads (50%) | called by mutect2, pindel, varscan2
- IGHMBP2 | c.1218del p.T407Pfs*16 | Frame Shift Del (DEL) | VAF 52/146 reads (36%) | called by mutect2, varscan2
- ILK | c.111dup p.H39Afs*13 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- ITSN1 | c.2314dup p.E772Gfs*5 | Frame Shift Ins (INS) | VAF 84/261 reads (32%) | called by mutect2, pindel, varscan2
- ITSN1 | c.5061_5066del p.D1688_Q1689del | In Frame Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- ITSN2 | c.2446del p.M816Cfs*41 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- JMJD1C | c.4526dup p.N1509Kfs*12 | Frame Shift Ins (INS) | VAF 36/134 reads (27%) | called by mutect2, pindel, varscan2
- KCND3 | c.1268del p.K423Rfs*34 | Frame Shift Del (DEL) | VAF 49/136 reads (36%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.2292_2301del p.I766Lfs*78 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | called by mutect2, pindel, varscan2
- KIF13B | c.4668del p.S1559Afs*3 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, varscan2
- MB | c.48dup p.K17Efs*5 | Frame Shift Ins (INS) | VAF 37/154 reads (24%) | called by mutect2, pindel, varscan2
- MDK | c.129dup p.P44Afs*46 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- MROH1 | c.2908G>A p.G970S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MRPS35 | c.902del p.N301Mfs*16 | Frame Shift Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- MSS51 | c.214_216del p.E72del | In Frame Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- MZF1 | c.474_475del p.E159Afs*13 | Frame Shift Del (DEL) | VAF 40/258 reads (16%) | called by mutect2, pindel, varscan2
- NCAPD2 | c.1914dup p.G639Wfs*9 | Frame Shift Ins (INS) | VAF 41/160 reads (26%) | called by mutect2, pindel, varscan2
- OPLAH | c.2669del p.G890Afs*8 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- PCGF3 | c.193del p.L65Cfs*26 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- PHC3 | c.2595_2597del p.E865del (on ENST00000494943 / NM_001308116.2; = p.E877del on NM_024947.4) | In Frame Del (DEL) | VAF 32/106 reads (30%) | called by pindel, varscan2
- PIDD1 | c.1549dup p.L517Pfs*50 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- POU5F2 | c.557del p.K186Sfs*3 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 201/318 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PXDN | c.2345del p.N782Tfs*21 | Frame Shift Del (DEL) | VAF 74/234 reads (32%) | called by mutect2, pindel, varscan2
- RAB12 | c.108del p.R37Gfs*22 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- RANBP2 | c.4429dup p.S1477Ffs*17 | Frame Shift Ins (INS) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- RBM18 | c.529del p.R177Gfs*21 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- SAFB | c.2451dup p.R818Qfs*3 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel
- SERPINF2 | c.1437dup p.M480Hfs*179 | Frame Shift Ins (INS) | VAF 45/214 reads (21%) | called by mutect2, pindel, varscan2
- SF3B2 | c.1657del p.M553Cfs*32 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- SHPRH | c.2577dup p.G860Wfs*9 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel
- SLC25A24 | c.570dup p.S191Ifs*74 | Frame Shift Ins (INS) | VAF 40/126 reads (32%) | called by mutect2, varscan2
- SLC9B1 | c.1432T>G p.L478V | Missense Mutation (SNP) | VAF 32/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- SSTR4 | c.27del p.G11Afs*61 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- SSX2IP | c.420del p.K140Nfs*13 | Frame Shift Del (DEL) | VAF 12/119 reads (10%) | called by mutect2, pindel, varscan2
- STAB1 | c.4394del p.G1465Afs*126 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- SUCO | c.2418_2420del p.I807del | In Frame Del (DEL) | VAF 15/48 reads (31%) | called by pindel, varscan2
- TBC1D9 | c.1076del p.K359Rfs*20 | Frame Shift Del (DEL) | VAF 78/225 reads (35%) | called by mutect2, pindel, varscan2
- TMEM222 | c.53del p.P18Rfs*17 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, varscan2
- TMEM51 | c.436dup p.R146Kfs*17 | Frame Shift Ins (INS) | VAF 25/141 reads (18%) | called by mutect2, pindel, varscan2
- TOM1L1 | c.454_455del p.Q152Vfs*9 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- TRAV26-1 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAV7 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TULP4 | c.2470del p.Q824Rfs*5 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- UACA | c.2667dup p.F890Ifs*2 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- ZBTB24 | c.1770_1778dup p.N591_T593dup | In Frame Ins (INS) | VAF 27/71 reads (38%) | called by mutect2, varscan2
- ZDHHC8 | c.1226del p.G409Afs*25 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- ZNF443 | c.622dup p.W208Lfs*9 | Frame Shift Ins (INS) | VAF 42/146 reads (29%) | called by mutect2, varscan2
- ACOT12 | c.66G>A p.A22= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV56895066; called by muse, mutect2
- ACOT7 | c.288C>T p.N96= (on ENST00000377855 / NM_181864.3; = p.N86= on NM_007274.4) | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs376851666; called by muse, mutect2, varscan2
- ADCY8 | c.1752T>C p.T584= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- ADRA1D | c.1107G>A p.P369= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1270979432, COSV65241321; called by muse, mutect2, varscan2
- AKAP8 | c.726G>T p.R242= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs773417870, COSV54103276; called by muse, mutect2, varscan2
- ALS2 | c.558C>A p.A186= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV51888841; called by muse, mutect2, varscan2
- ANK1 | c.42C>T p.I14= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV55885825; called by muse, mutect2, varscan2
- ARHGAP36 | c.1317C>T p.R439= | Silent (SNP) | VAF 54/73 reads (74%) | catalogued as rs189514802, COSV52264345; called by muse, mutect2, varscan2
- ASIC5 | c.1377G>A p.T459= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs775001623, COSV73332815; called by muse, mutect2
- BBX | c.2466C>T p.S822= (on ENST00000325805 / NM_001142568.3; = p.S792= on NM_020235.7) | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV57887994; called by muse, mutect2, varscan2
- BRIX1 | c.447C>T p.L149= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as rs143239489, COSV59131576; called by muse, mutect2, varscan2
- C3orf56 | c.417C>T p.S139= | Silent (SNP) | VAF 137/370 reads (37%) | catalogued as rs1304162290, COSV101228918; called by muse, mutect2, varscan2
- C5 | c.4569C>T p.A1523= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs778838090, COSV56326893; called by muse, mutect2, varscan2
- CACNA1H | c.1794C>T p.A598= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs369322856; ClinVar: likely benign; called by muse, mutect2, varscan2
- CADM2 | c.243C>T p.R81= (on ENST00000407528 / NM_001167674.2; = p.R83= on NM_153184.4) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs747906551, COSV67367857; called by muse, mutect2, varscan2
- CALR | c.774C>T p.D258= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs773932539, COSV57129343; called by muse, mutect2, varscan2
- CASZ1 | c.531C>T p.Y177= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1395362341, COSV59731214; called by muse, mutect2, varscan2
- CBX6 | c.129G>A p.E43= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs758098522, COSV53321286; called by muse, mutect2, varscan2
- CEP170B | c.366C>T p.S122= (on ENST00000453495; = p.S52= on NM_015005.3) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs776008979, COSV69025262; called by muse, mutect2
- CHCHD6 | c.693C>T p.A231= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs771592437, COSV52064943; called by muse, mutect2, varscan2
- CHRNA1 | c.1231C>T p.L411= (on ENST00000261007 / NM_001039523.3; = p.L386= on NM_000079.4) | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV53682904, COSV53683449; called by muse, mutect2, varscan2
- CHST7 | c.675C>T p.C225= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV52100412; called by muse, mutect2, varscan2
- CMPK2 | c.426C>A p.T142= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV56775209; called by muse, mutect2, varscan2
- COL28A1 | c.1083G>A p.Q361= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV68083024; called by muse, mutect2, varscan2
- COL6A5 | c.6645T>C p.S2215= (on ENST00000312481; = p.S2211= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99591774; called by muse, mutect2, varscan2
- COPB2 | c.423C>T p.H141= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as rs1451244991, COSV60813072; called by muse, mutect2, varscan2
- CRAT | c.936C>T p.G312= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs372666934; called by muse, mutect2, varscan2
- CYB561D2 | c.252C>T p.R84= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV51703010; called by muse, mutect2, varscan2
- DCDC1 | c.4236G>A p.V1412= (on ENST00000597505 / NM_001367979.1; = p.V519= on NM_020869.3) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV58001195; called by muse, mutect2, varscan2
- DDX55 | c.645G>A p.A215= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs1322582650, COSV53016629; called by muse, mutect2, varscan2
- DIAPH1 | c.1815T>C p.S605= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV53881210; called by muse, mutect2, varscan2
- DIDO1 | c.4521C>T p.V1507= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV56626790; called by muse, mutect2, varscan2
- DLG5 | c.3210G>A p.R1070= | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- DNAH3 | c.7608C>T p.T2536= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV54531348, COSV99770748; called by muse, mutect2, varscan2
- DNAH5 | c.12375G>A p.A4125= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs140284455; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH9 | c.13401G>A p.K4467= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52357941; called by muse, mutect2, varscan2
- DOCK2 | c.1710T>G p.S570= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV56968199; called by muse, mutect2, varscan2
- EIF5B | c.2262A>G p.A754= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV56814303; called by muse, mutect2, varscan2
- ELF4 | c.585C>T p.I195= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57453397; called by muse, mutect2, varscan2
- FANCB | c.1344T>G p.P448= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV60760671; called by muse, varscan2
- FASLG | c.183A>G p.P61= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs755282797, COSV60680382; called by muse, mutect2, varscan2
- FAT4 | c.1284C>T p.R428= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs546059430, COSV67890945; called by muse, mutect2, varscan2
- FBLN2 | c.2118C>T p.P706= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs765318313, COSV55486819; called by muse, mutect2, varscan2
- FKBP9 | c.522C>T p.N174= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1314548179, COSV54232401; called by muse, mutect2, varscan2
- FSIP2 | c.16702A>C p.R5568= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100553770; called by muse, mutect2, varscan2
- FTSJ1 | c.330G>A p.A110= | Silent (SNP) | VAF 77/115 reads (67%) | catalogued as rs781843691, COSV50025763; called by muse, mutect2, varscan2
- FUT10 | c.477T>C p.F159= | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV59452587; called by muse, mutect2, varscan2
- GDPD1 | c.654C>A p.P218= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV52382571; called by muse, mutect2, varscan2
- GET3 | c.738C>T p.C246= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs758580152, COSV62001878; called by muse, mutect2, varscan2
- GIGYF1 | c.993C>T p.F331= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV51943763; called by muse, mutect2, varscan2
- GOT1 | c.126C>T p.R42= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as COSV65147532; called by muse, mutect2, varscan2
- GPC5 | c.156G>A p.P52= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV65608936; called by muse, mutect2, varscan2
- GPR150 | c.675G>A p.P225= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV66168412; called by muse, mutect2, varscan2
- GPR171 | c.771C>T p.C257= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs566034239, COSV56384806; called by muse, mutect2, varscan2
- GPR20 | c.708C>T p.R236= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs770199502, COSV66684604; called by muse, mutect2, varscan2
- GRN | c.1695C>T p.C565= | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as rs63751248, COSV50007746; ClinVar: not provided; called by muse, mutect2, varscan2
- GSTCD | c.801C>A p.A267= (on ENST00000360505 / NM_001031720.3; = p.A180= on NM_024751.3) | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs774926084, COSV100853831, COSV64734168; called by muse, mutect2, varscan2
- HELT | c.126G>A p.A42= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1156669428, COSV58819775; called by muse, mutect2, varscan2
- HIPK1 | c.3003C>A p.T1001= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV61248862; called by muse, mutect2, varscan2
- HK1 | c.1227G>A p.T409= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as rs367932087; called by muse, mutect2, varscan2
- HOXB3 | c.223A>C p.R75= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV61144161; called by muse, mutect2
- HOXD13 | c.603G>A p.Q201= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV66832721; called by muse, mutect2, varscan2
- HSPA2 | c.1665G>T p.T555= | Silent (SNP) | VAF 49/236 reads (21%) | catalogued as rs1037207680, COSV55970407; called by muse, mutect2, varscan2
- HTR1A | c.666G>A p.A222= | Silent (SNP) | VAF 111/293 reads (38%) | catalogued as COSV60500938, COSV60502320; called by muse, mutect2, varscan2
- HTR5A | c.468C>T p.C156= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as COSV55283419, COSV55283730; called by muse, mutect2, varscan2
- ICAM3 | c.570C>T p.C190= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV50329386; called by muse, mutect2
- IGF1R | c.2745G>A p.S915= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs757589571, COSV51308168; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- IGFN1 | c.3609G>A p.V1203= (on ENST00000295591 / NM_001367841.1; = p.V3660= on NM_001164586.2) | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs766134966, COSV55176300; called by muse, mutect2, varscan2
- IGKV6D-21 | c.294A>G p.E98= | Silent (SNP) | VAF 79/203 reads (39%) | called by muse, mutect2, varscan2
- INHBC | c.855A>C p.A285= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs975042605, COSV59005564; called by muse, mutect2, varscan2
- JAKMIP1 | c.453G>A p.L151= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV51535937; called by muse, mutect2, varscan2
- JPH4 | c.1395C>A p.A465= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV58113616; called by muse, mutect2, varscan2
- KCNK4 | c.450C>T p.I150= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs780347185, COSV60453958; called by muse, mutect2, varscan2
- KMT2C | c.4776C>T p.S1592= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV51458007; called by muse, mutect2, varscan2
- LILRA4 | c.198A>G p.S66= | Silent (SNP) | VAF 72/193 reads (37%) | catalogued as COSV52493111; called by muse, mutect2, varscan2
- LRIT1 | c.1128C>T p.N376= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV64513009; called by muse, mutect2, varscan2
- LRP1 | c.5460C>T p.S1820= | Silent (SNP) | VAF 54/168 reads (32%) | catalogued as rs1303824469, COSV54516558; called by muse, mutect2, varscan2
- MAMDC4 | c.3234C>T p.G1078= (on ENST00000445819; = p.G999= on NM_206920.3) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56376368; called by muse, mutect2
- MAP1A | c.1636C>T p.L546= | Silent (SNP) | VAF 79/225 reads (35%) | catalogued as COSV55810281; called by muse, mutect2, varscan2
- MBNL2 | c.348C>T p.F116= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1253708599, COSV59122686; called by muse, mutect2, varscan2
- MCC | c.1443C>T p.G481= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs746570750; called by muse, mutect2, varscan2
- MINAR1 | c.2277C>T p.D759= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV59584201; called by muse, mutect2, varscan2
- MN1 | c.3414G>A p.P1138= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV56559593; called by muse, mutect2, varscan2
- MSR1 | c.957C>T p.L319= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV50516941; called by muse, mutect2
- MTR | c.141C>T p.N47= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as rs144151735, COSV63968558; called by muse, mutect2, varscan2
- MUC16 | c.5832A>G p.E1944= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV67476241; called by muse, mutect2, varscan2
- MVP | c.2055C>T p.R685= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs149725123; called by muse, mutect2, varscan2
- MYH8 | c.984C>T p.D328= | Silent (SNP) | VAF 120/351 reads (34%) | catalogued as rs889687395, COSV67967709; called by muse, mutect2, varscan2
- NARF | c.408G>A p.T136= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs775565156, COSV59110424; called by muse, mutect2, varscan2
- NCKAP1L | c.1071T>C p.D357= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as COSV53208746; called by muse, mutect2, varscan2
- NOL4L | c.180G>A p.T60= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs1411040128, COSV62889698; called by muse, mutect2, varscan2
- NOMO3 | c.1467C>T p.T489= | Silent (SNP) | VAF 123/360 reads (34%) | catalogued as rs749544353, COSV53769467; called by muse, mutect2, varscan2
- NXF1 | c.942G>A p.G314= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs1354593381, COSV53674748; called by muse, mutect2, varscan2
- OR1K1 | c.372C>T p.Y124= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs761878301, COSV52956645; called by muse, mutect2, varscan2
- OR2M3 | c.141C>G p.L47= | Silent (SNP) | VAF 183/544 reads (34%) | catalogued as rs1019931646, COSV71759126; called by muse, mutect2, varscan2
- OR2T35 | c.576G>A p.T192= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1345528643; called by mutect2, varscan2
- P2RY8 | c.960G>A p.T320= | Silent (SNP) | VAF 62/113 reads (55%) | catalogued as rs779291412, COSV67177684; called by muse, mutect2, varscan2
- PCDH10 | c.975A>G p.Q325= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as COSV52097597; called by muse, mutect2, varscan2
- PCDHB16 | c.1506C>T p.S502= | Silent (SNP) | VAF 30/225 reads (13%) | catalogued as COSV53364928; called by muse, mutect2
- PCDHB3 | c.873T>G p.T291= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV50585749; called by muse, mutect2, varscan2
- PCDHB4 | c.1344C>T p.P448= | Silent (SNP) | VAF 153/476 reads (32%) | catalogued as rs1337500121, COSV52023949; called by muse, mutect2, varscan2
- PCDHB4 | c.1503C>T p.S501= | Silent (SNP) | VAF 101/841 reads (12%) | called by muse, mutect2, varscan2
- PIWIL2 | c.2268C>T p.S756= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs553102129, COSV63252362; called by muse, mutect2, varscan2
- PKDCC | c.660G>A p.Q220= | Silent (SNP) | VAF 77/286 reads (27%) | catalogued as COSV54307399; called by muse, mutect2, varscan2
- PKHD1 | c.8586T>G p.A2862= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV61883008; called by muse, varscan2
- PLPPR3 | c.1755G>A p.A585= (on ENST00000520876 / NM_001270366.2; = p.A613= on NM_024888.2) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV62460778; called by muse, mutect2, varscan2
- PLXDC2 | c.231G>A p.T77= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs751339773, COSV65912536, COSV65923103; called by muse, mutect2, varscan2
- PLXND1 | c.696C>T p.F232= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV60715567; called by muse, mutect2, varscan2
- POLR3A | c.21G>A p.R7= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV62602671; called by muse, mutect2, varscan2
- POU4F3 | c.816C>T p.S272= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV57943853; called by muse, mutect2, varscan2
- PRR23B | c.168G>A p.A56= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1194016192, COSV61494148; called by muse, mutect2, varscan2
- PSAPL1 | c.1035C>A p.P345= | Silent (SNP) | VAF 69/229 reads (30%) | catalogued as COSV59843528; called by muse, mutect2, varscan2
- PSMA4 | c.135T>C p.L45= | Silent (SNP) | VAF 89/216 reads (41%) | catalogued as COSV50384834; called by muse, mutect2, varscan2
- PTCH1 | c.1998G>A p.T666= | Silent (SNP) | VAF 93/265 reads (35%) | catalogued as rs369710438, COSV59473269; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PTPRF | c.5589C>T p.G1863= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs138441028; called by muse, mutect2, varscan2
- RAB40C | c.504G>A p.T168= | Silent (SNP) | VAF 73/219 reads (33%) | catalogued as rs777343433, COSV50194202; called by muse, mutect2, varscan2
- RNF145 | c.735C>T p.S245= (on ENST00000424310 / NM_001199383.2; = p.S273= on NM_144726.2) | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV50867889, COSV99193649; called by muse, mutect2, varscan2
- RORA | c.33C>T p.A11= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV59534961; called by muse, mutect2
- RPF2 | c.525C>T p.I175= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs1475961660, COSV64369846; called by muse, mutect2, varscan2
- RRAS | c.630C>T p.G210= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs745391652, COSV55868725, COSV99881968; called by muse, mutect2, varscan2
- S100A9 | c.114A>G p.K38= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV64199745; called by muse, mutect2, varscan2
- SH3BP5L | c.565C>A p.R189= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV63539498, COSV63539522; called by muse, mutect2, varscan2
- SLC19A3 | c.921G>A p.A307= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs776544411, COSV51451622; called by muse, mutect2, varscan2
- SLC24A4 | c.693C>G p.G231= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs761532299, COSV54115818; called by muse, mutect2, varscan2
- SLC25A37 | c.477G>A p.A159= | Silent (SNP) | VAF 110/361 reads (30%) | catalogued as COSV51564576; called by muse, mutect2, varscan2
- SLC45A1 | c.303C>T p.Y101= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs769137840, COSV57095723; called by muse, mutect2, varscan2
- SLC7A1 | c.1161C>T p.I387= | Silent (SNP) | VAF 108/337 reads (32%) | catalogued as rs377527629; called by muse, mutect2, varscan2
- SMURF1 | c.1479G>A p.G493= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as rs771196252, COSV62816281; called by muse, mutect2, varscan2
- SOAT2 | c.268T>C p.L90= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs764655391, COSV56857612; called by muse, mutect2, varscan2
- SPATA31E1 | c.72C>G p.P24= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV57793014, COSV57795239; called by muse, mutect2, varscan2
- STK35 | c.1533T>C p.A511= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV55691597, COSV55692276; called by muse, mutect2, varscan2
- SYTL1 | c.1656A>G p.L552= (on ENST00000543823; = p.L540= on NM_032872.3) | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV58872827; called by muse, mutect2, varscan2
- TACSTD2 | c.618G>A p.R206= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV64667200, COSV64667352; called by muse, mutect2, varscan2
- TAF5L | c.705C>T p.N235= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs202211536, COSV51082843; called by muse, mutect2
- TDRD9 | c.4137G>A p.V1379= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV59149954; called by muse, mutect2
- TIPARP | c.18C>T p.T6= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs190841318, COSV55813335; called by muse, mutect2, varscan2
- TLE2 | c.1170C>T p.P390= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs145514117, COSV53581038; called by muse, mutect2, varscan2
- TLE5 | c.588G>A p.S196= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs376230542; called by muse, mutect2, varscan2
- TMEM177 | c.678C>T p.A226= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs753379936, COSV55609054; called by muse, mutect2, varscan2
- TTN | c.20943G>T p.G6981= (on ENST00000591111; = p.G6054= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV60159630; called by muse, mutect2, varscan2
- TUBAL3 | c.1218C>T p.Y406= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as rs367579573; called by muse, mutect2, varscan2
- TUBGCP2 | c.2265C>T p.C755= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as rs1299868855, COSV53306482; called by muse, mutect2, varscan2
- UNC13C | c.3219T>C p.N1073= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52891787; called by muse, mutect2
- USP49 | c.657G>A p.A219= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1409345390, COSV51898659; called by muse, mutect2, varscan2
- VILL | c.273C>T p.T91= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV52185702; called by muse, mutect2, varscan2
- WDFY2 | c.285T>C p.F95= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1051977048, COSV53290828; called by muse, mutect2, varscan2
- WDR17 | c.771T>A p.S257= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as COSV54577267; called by muse, mutect2, varscan2
- WNT4 | c.411C>T p.G137= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as COSV51604344; called by muse, mutect2, varscan2
- XAB2 | c.639C>A p.A213= | Silent (SNP) | VAF 87/223 reads (39%) | catalogued as COSV100601844, COSV64321944; called by muse, mutect2, varscan2
- ZBTB4 | c.2769G>A p.P923= | Silent (SNP) | VAF 108/418 reads (26%) | catalogued as rs769689249, COSV60141006; called by muse, mutect2, varscan2
- ZBTB45 | c.363T>C p.I121= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as COSV63524480; called by muse, mutect2, varscan2
- ZNF148 | c.339C>T p.S113= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs529285699, COSV62305634; called by muse, mutect2
- ZNF516 | c.3345C>A p.A1115= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV101487192; called by muse, mutect2
- ZNF653 | c.1842C>T p.P614= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs896772895, COSV53403660; called by muse, mutect2, varscan2
- ZSWIM1 | c.951A>G p.K317= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as COSV54848924; called by muse, mutect2, varscan2
- ZSWIM4 | c.2403C>G p.G801= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as COSV54323535; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1150C>T | Intron (SNP) | VAF 33/80 reads (41%) | catalogued as rs371231811; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851927 del A | 3'Flank (DEL) | VAF 58/78 reads (74%) | catalogued as rs760456851; called by mutect2, varscan2
- BRD4 | c.2158+504G>A | Intron (SNP) | VAF 26/58 reads (45%) | catalogued as rs867355043, COSV99649879; called by muse, mutect2, varscan2
- DCHS2 | n.7162A>G | RNA (SNP) | VAF 45/106 reads (42%) | catalogued as COSV61774669; called by muse, mutect2, varscan2
- DCHS2 | n.4513A>C | RNA (SNP) | VAF 60/192 reads (31%) | catalogued as COSV61774675; called by muse, mutect2, varscan2
- FOLH1B | n.1967C>A | RNA (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- LINC00174 | n.3324C>T | RNA (SNP) | VAF 7/14 reads (50%) | catalogued as rs369302174; called by muse, varscan2
- MGAM | c.4618+8648C>A | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101527359; called by muse, mutect2, varscan2
- MIR518B | n.41T>C | RNA (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- PMVK | c.*1T>C | 3'UTR (SNP) | VAF 28/299 reads (9%) | catalogued as COSV100870489; called by muse, mutect2
- RUSC1 | c.-180T>C | 5'UTR (SNP) | VAF 23/62 reads (37%) | catalogued as COSV52740864; called by muse, mutect2, varscan2
- SHMT1 | c.243-152A>G | Intron (SNP) | VAF 94/237 reads (40%) | catalogued as rs1246768932; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928740 G>T | 3'Flank (SNP) | VAF 52/159 reads (33%) | catalogued as COSV60486960; called by muse, mutect2, varscan2
- ZBED3 | c.-152-1735G>A | Intron (SNP) | VAF 28/74 reads (38%) | catalogued as COSV99672907; called by muse, mutect2, varscan2
- ZNF99 | c.4-627T>G | Intron (SNP) | VAF 15/51 reads (29%) | catalogued as COSV68056029; called by muse, mutect2, varscan2
